FM case AD4498 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/3fc0cd12-48c0-4742-b1d0-e1a79ac3a12b

Male, 52.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3). Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
